CCDI case PBCLCC — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/6c5cac13-1ee1-4297-bce2-cff161d27815

Demographics
Sex at birth: female; Race: white.

Diagnoses (1)
1. Ependymoma, NOS: ICD-O-3 morphology code: 9391/3; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 1.8 years (658 days).

Biospecimens (3 samples)
- Sample 0DUVT0: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DUVT9: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DUVTP: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
